Somatic mutation profile of tumor specimen ALCH-B0AA-TTP1-A (aliquot ALCH-B0AA-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B0AA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,447 days).
Specimen ALCH-B0AA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1a29339-cd1d-4fec-90f0-e1b148c62a66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AA-NB1-A (Blood Derived Normal), aliquot ALCH-B0AA-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/568af09c-0984-4ee4-bce3-c2e3faa9bcc4

The open-access MAF lists 85 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 16, Intron 5, Splice Site 1, 5'Flank 1, 5'UTR 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.5831G>A p.G1944E | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV54952094; called by muse, mutect2, varscan2
- DAB2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV57913448; called by muse, mutect2
- FLG | c.5090C>T p.T1697I | Missense Mutation (SNP) | VAF 34/530 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.137); catalogued as rs768193909, COSV64247856; called by muse, mutect2
- GALNT17 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV61187244; called by muse, mutect2
- GLI3 | c.2606C>A p.P869H | Missense Mutation (SNP) | VAF 39/655 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67885583; called by muse, mutect2
- GRK1 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.798); catalogued as COSV100175266; called by muse, mutect2
- HPS4 | c.2010C>G p.F670L | Missense Mutation (SNP) | VAF 31/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61105797; called by muse, mutect2
- KIF26A | c.1770C>A p.S590R | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); catalogued as rs903102198; called by muse, mutect2
- KIF4B | c.2916G>T p.K972N | Missense Mutation (SNP) | VAF 26/529 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV70527626; called by muse, mutect2
- KRTAP20-3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/118 reads (7%) | PolyPhen benign (0); catalogued as rs1448752114; called by muse, mutect2
- NCKAP5 | c.5456C>A p.S1819Y | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.106); catalogued as COSV58437073; called by muse, mutect2
- OR1L4 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99413937; called by muse, mutect2
- PDYN | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 23/790 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.201); catalogued as COSV54102687; called by muse, mutect2
- PDZRN3 | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470966941; called by muse, mutect2
- PDZRN3 | c.2040C>A p.S680R | Missense Mutation (SNP) | VAF 24/704 reads (3%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.826); catalogued as COSV55205979, COSV99732848; called by muse, mutect2
- REXO2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56276744; called by muse, mutect2
- SAMD4A | c.1873C>A p.R625S | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV51876345; called by muse, mutect2
- STAT4 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.922); catalogued as rs1305163633; called by muse, mutect2
- ADAMTS8 | c.2002C>G p.H668D | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2
- ANKRD63 | c.981G>T p.L327F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- APOA4 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 34/1072 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- C2CD6 | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 37/621 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEACAM20 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 18/589 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLK2 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 22/655 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- COL6A5 | c.4609-1G>T p.X1537_splice | Splice Site (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- CYP4F11 | c.695T>A p.V232E | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- DBX2 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- DMGDH | c.2521G>T p.V841F | Missense Mutation (SNP) | VAF 23/644 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2
- DNAH14 | c.3911A>T p.Q1304L (on ENST00000445597; = p.Q1714L on NM_001367479.1) | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2
- DRD1 | c.217G>C p.V73L | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2
- DSG3 | c.2570C>A p.A857E | Missense Mutation (SNP) | VAF 39/623 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM47B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 15/355 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.242); called by muse, mutect2
- FSCB | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 28/339 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.042); called by muse, mutect2
- HGF | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.127); called by muse, mutect2
- HIP1 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HMCN1 | c.13682C>A p.P4561Q | Missense Mutation (SNP) | VAF 48/616 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQSEC3 | c.2991G>T p.Q997H (on ENST00000538872 / NM_001170738.2; = p.Q694H on NM_015232.1) | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- KIAA1549L | c.710C>A p.S237Y (on ENST00000321505; = p.S534Y on NM_012194.3) | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP13-2 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- MUC16 | c.8939C>T p.S2980L | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); called by muse, mutect2
- NALCN | c.1784T>C p.V595A | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NPHP3 | c.2047G>T p.A683S | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.341); called by muse, mutect2
- PCDHA4 | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 78/1256 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.046); called by muse, mutect2
- PDE10A | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2
- PDHX | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 36/526 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PHOSPHO2 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- PLSCR2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2
- POMT2 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 31/832 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.101); called by muse, mutect2
- PPP4R3C | c.924A>T p.K308N | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- PTGIS | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 86/517 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- SATL1 | c.1435A>T p.S479C (on ENST00000395409; = p.S666C on NM_001367857.2) | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); called by muse, mutect2
- SLC8A1 | c.1613G>T p.G538V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPTA1 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 42/676 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- STMN4 | c.411C>A p.F137L (on ENST00000265770 / NM_001283054.2; = p.F164L on NM_030795.4) | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2
- SYTL4 | c.935A>T p.D312V | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2
- TINAG | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- TMEM132C | c.3052C>A p.H1018N | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2
- TMEM132E | c.829G>T p.A277S (on ENST00000321639; = p.A367S on NM_001304438.2) | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2
- TRIM64B | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 32/1041 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR36 | c.2474C>T p.S825L | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2
- WDR87 | c.8032C>G p.H2678D | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2
- IGKV1D-42 | c.175C>T p.L59= | Silent (SNP) | VAF 10/199 reads (5%) | called by muse, mutect2
- IGLJ6 | c.66C>A p.V22= | Silent (SNP) | VAF 18/470 reads (4%) | called by muse, mutect2
- KIAA1549 | c.1107G>A p.A369= | Silent (SNP) | VAF 26/342 reads (8%) | catalogued as rs370830770; called by muse, mutect2
- MARK1 | c.543T>G p.R181= | Silent (SNP) | VAF 14/245 reads (6%) | called by muse, mutect2
- METTL21C | c.676A>C p.R226= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- NCKIPSD | c.1383C>T p.L461= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as rs1482290334, COSV53661212; called by muse, mutect2
- OR2A4 | c.741T>A p.I247= | Silent (SNP) | VAF 21/429 reads (5%) | called by muse, mutect2
- PCLO | c.14769G>T p.V4923= | Silent (SNP) | VAF 36/642 reads (6%) | catalogued as COSV61660241; called by muse, mutect2
- SEMA3F | c.2076G>A p.V692= | Silent (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- SLC45A1 | c.1035G>A p.T345= | Silent (SNP) | VAF 29/789 reads (4%) | catalogued as rs1485626604, COSV57096777, COSV57099156; called by muse, mutect2
- TRPV3 | c.1209G>T p.V403= | Silent (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
- UBIAD1 | c.693C>T p.S231= | Silent (SNP) | VAF 20/602 reads (3%) | called by muse, mutect2
- VAT1L | c.966C>A p.L322= | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- WRAP73 | c.99C>T p.V33= | Silent (SNP) | VAF 13/223 reads (6%) | called by muse, mutect2
- ZEB2 | c.772C>A p.R258= | Silent (SNP) | VAF 20/622 reads (3%) | catalogued as COSV57951163, COSV57965845; called by muse, mutect2
- ZNF76 | c.1524G>A p.V508= | Silent (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- CCT5 | chr5:10249991 G>A | 5'Flank (SNP) | VAF 14/270 reads (5%) | catalogued as rs1325380478; called by muse, mutect2
- FAM53A | c.883-2734C>T | Intron (SNP) | VAF 12/182 reads (7%) | catalogued as rs969905039; called by muse, mutect2
- NPAT | c.38-11001G>T | Intron (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- OR7E5P | n.217A>T | RNA (SNP) | VAF 27/470 reads (6%) | called by muse, mutect2
- PFKM | c.85+2515G>C | Intron (SNP) | VAF 12/182 reads (7%) | catalogued as rs1436506039; called by muse, mutect2
- PTPDC1 | c.83-683T>G | Intron (SNP) | VAF 13/328 reads (4%) | called by muse, mutect2
- SYT14 | c.61+13248G>T | Intron (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- ZDHHC13 | c.-4G>A | 5'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
